Somatic mutation profile of tumor specimen TCGA-CZ-5462-01A (aliquot TCGA-CZ-5462-01A-01D-1501-10) from TCGA case TCGA-CZ-5462, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 83.9 years (30,659 days).
Specimen TCGA-CZ-5462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac93bc6d-5cf5-4302-8504-7c381f9a250a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5462-11A (Solid Tissue Normal), aliquot TCGA-CZ-5462-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc959a9d-3b10-4d28-9a63-a2eafd05e58f

The open-access MAF lists 66 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 41, Silent 11, Frame Shift Del 10, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4780G>A p.G1594S | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.314); catalogued as COSV70032283; called by muse, mutect2, varscan2
- ADAM10 | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 104/507 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53052234, COSV99546847; called by muse, mutect2, varscan2
- AKNA | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV56313313; called by muse, mutect2, varscan2
- AMPH | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV57745337; called by muse, mutect2, varscan2
- ANKRD34B | c.243C>A p.D81E | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58614084; called by muse, mutect2, varscan2
- ASCC3 | c.2287G>A p.V763I | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV61229906; called by muse, mutect2, varscan2
- BARD1 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV53613048; called by muse, mutect2
- BPIFB1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV53606270, COSV53606994; called by muse, mutect2, varscan2
- CA10 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 140/579 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.018); catalogued as COSV53354863, COSV99562080; called by muse, mutect2, varscan2
- CBR4 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV60370292; called by muse, mutect2
- CCN3 | c.859T>A p.Y287N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52384246; called by muse, mutect2, varscan2
- CEP250 | c.7133C>T p.A2378V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100698919; called by mutect2, varscan2
- CFAP57 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV65264700; called by muse, mutect2, varscan2
- COL5A3 | c.438-1G>A p.X146_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53412727; called by muse, mutect2, varscan2
- CPXM2 | c.1479+1G>A p.X493_splice | Splice Site (SNP) | VAF 23/174 reads (13%) | catalogued as COSV53864097; called by muse, mutect2, varscan2
- CTNS | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV50441305; called by muse, mutect2, varscan2
- CXCR6 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV56116898; called by muse, mutect2, varscan2
- DDB1 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV57103677; called by muse, mutect2, varscan2
- DISP1 | c.4421G>T p.R1474M | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV52660566; called by muse, mutect2, varscan2
- DMRT3 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as rs374319022, COSV51907430; called by muse, mutect2, varscan2
- EPHA5 | c.2891C>A p.S964Y | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.299); catalogued as COSV56651058, COSV99896979; called by muse, mutect2, varscan2
- ETV1 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54144460; called by muse, mutect2, varscan2
- GTF2I | c.2585T>A p.V862D (on ENST00000573035 / NM_032999.4; = p.V821D on NM_001518.5) | Missense Mutation (SNP) | VAF 60/651 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100259346, COSV60401808; called by muse, mutect2
- HACE1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 59/229 reads (26%) | catalogued as COSV53503547; called by muse, mutect2, varscan2
- HMCN1 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV54887636, COSV54909051, COSV99631461; called by muse, mutect2, varscan2
- IL20RB | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59048263; called by muse, mutect2, varscan2
- INTU | c.2425C>A p.Q809K | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV58872436; called by muse, mutect2, varscan2
- KIR3DL2 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV99552034; called by muse, mutect2, varscan2
- LAMA2 | c.442del p.R148Gfs*24 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | catalogued as COSV70345971; called by mutect2, pindel, varscan2
- LTBP4 | c.3805del p.V1269Cfs*3 (on ENST00000308370 / NM_001042544.1; = p.V1232Cfs*3 on NM_003573.2) | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as COSV99199678; called by mutect2, pindel, varscan2
- PCDH7 | c.1873G>T p.V625L | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62340079; called by muse, mutect2, varscan2
- PCNX1 | c.4292A>C p.E1431A | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53096388; called by muse, mutect2, varscan2
- PIK3CG | c.1647C>A p.N549K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV63249496; called by muse, mutect2, varscan2
- PLXNA4 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58107344, COSV58134522; called by muse, mutect2, varscan2
- RASA1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as COSV57197067; called by muse, mutect2, varscan2
- RGL1 | c.2021A>G p.K674R (on ENST00000360851 / NM_001297672.2; = p.K709R on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV58987737; called by muse, mutect2, varscan2
- SLC9A4 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 192/1012 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54835251; called by muse, mutect2, varscan2
- SPTA1 | c.3668G>A p.R1223Q | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148714399, COSV63754963; called by muse, mutect2, varscan2
- TGM5 | c.1690T>C p.F564L (on ENST00000220420 / NM_201631.4; = p.F482L on NM_004245.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.492); catalogued as COSV99588965; called by muse, varscan2
- TMEM255B | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.361); catalogued as rs756032682, COSV64711628; called by muse, mutect2, varscan2
- TMEM71 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200344505, COSV100785636, COSV63457874; called by muse, mutect2, varscan2
- TMPRSS11D | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs763489466, COSV52224005; called by muse, mutect2, varscan2
- TRAPPC10 | c.3020T>C p.V1007A | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as rs777601839, COSV52378327; called by muse, mutect2
- TTN | c.92806A>T p.I30936F (on ENST00000591111; = p.I23512F on NM_003319.4) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | PolyPhen benign (0.399); catalogued as COSV60132383; called by muse, mutect2, varscan2
- UBR2 | c.3997T>A p.W1333R | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65750581; called by muse, mutect2, varscan2
- ZNF24 | c.559A>T p.R187W | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54348777; called by muse, mutect2, varscan2
- ANKRD11 | c.3907del p.V1303Sfs*15 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- DENND4A | c.1680_1698del p.L560Ffs*9 | Frame Shift Del (DEL) | VAF 66/404 reads (16%) | called by mutect2, pindel
- LGALS3BP | c.1676T>C p.F559S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- MYCBP2 | c.7296del p.K2432Nfs*23 (on ENST00000357337; = p.K2470Nfs*23 on NM_015057.5) | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | called by mutect2, varscan2
- PITPNB | c.565del p.Q189Rfs*8 | Frame Shift Del (DEL) | VAF 69/288 reads (24%) | called by mutect2, pindel, varscan2
- RAD23A | c.175_182del p.V59Qfs*7 | Frame Shift Del (DEL) | VAF 36/187 reads (19%) | called by mutect2, pindel
- SEC23A | c.2274del p.K758Nfs*22 | Frame Shift Del (DEL) | VAF 47/267 reads (18%) | called by mutect2, pindel, varscan2
- SLC45A2 | c.807_810del p.I271Rfs*8 | Frame Shift Del (DEL) | VAF 50/297 reads (17%) | called by mutect2, pindel, varscan2
- ZAN | c.7265del p.N2422Mfs*32 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- ACOT9 | c.84C>T p.N28= | Silent (SNP) | VAF 129/318 reads (41%) | catalogued as rs763793281, COSV60538044; called by muse, mutect2, varscan2
- ACSBG1 | c.84C>T p.S28= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV51907292; called by muse, mutect2, varscan2
- DDB1 | c.1641A>T p.G547= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV57103663; called by muse, mutect2, varscan2
- KIF4B | c.954C>T p.S318= | Silent (SNP) | VAF 89/582 reads (15%) | catalogued as COSV70529958; called by muse, mutect2, varscan2
- KLF8 | c.486T>C p.T162= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV63848077; called by muse, mutect2, varscan2
- NCKAP5 | c.4071C>T p.S1357= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV58450907; called by muse, varscan2
- PRPF19 | c.24T>A p.S8= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV57128282; called by muse, mutect2, varscan2
- PTPRT | c.4128C>A p.V1376= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100626687, COSV61990108; called by muse, mutect2, varscan2
- SFTPD | c.399C>T p.G133= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100954458, COSV64853233; called by muse, mutect2, varscan2
- SYK | c.966G>A p.P322= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as rs200697355, COSV65327852; called by muse, mutect2, varscan2
- TTN | c.34968T>A p.V11656= (on ENST00000591111; = p.V10729= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as COSV60132418; called by muse, mutect2, varscan2
